Gene-level copy-number profile of tumor specimen TCGA-32-2632-01A from TCGA case TCGA-32-2632, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.2 years (29,281 days).
Specimen TCGA-32-2632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b9da9afd-281b-4bef-9b3a-c73d62b92a2b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-32-2632-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4453d3a5-6dcb-4f1f-87b0-0130c4a02715

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,918; copy number 2: 43,992; copy number 3: 8,823; copy number 4: 2,966; copy number 6: 17; copy number 7: 22; copy number 9: 3; copy number 14: 6; copy number 18: 9; copy number 31: 53; copy number 36: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-32-2632-01A-01D-0911-01): tumor purity 0.59, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 121 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,178,931–204,728,106, 53 genes, copy number 31: CHI3L1, CHIT1, NPM1P40, LINC01353, LINC01136, BTG2, RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr7:50,093,279–55,572,988, 68 genes, copy number 6–36 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
